Surgical pathology report (de-identified scan), TCGA case TCGA-51-4079, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-51-4079-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

A: Lung, right upper lobe, lobectomy

Tumor histologic type [REDACTED]: squamous carcinoma

Tumor histologic grade [REDACTED]: moderately differentiated,
focally keratinizing

Tumor size (greatest dimension): 5 cm

Other structures involved: none

Pleural involvement: not identified

In situ carcinoma: present

Invasion:

venous - not identified

arterial - not identified

lymphatic - not identified

perineural - not identified

Surgical margins: not involved

Lymph nodes: Peribronchial - No metastatic carcinoma
identified (0/5).

Separately submitted lymph nodes, see specimens B-E,
below.

AJCC stage: pT2 pN0 pMx

This staging information is based on this pathologic

[page 2 of 4]
specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

B: Lymph node, station 11, removal
- No metastatic carcinoma identified (0/1).

C: Lymph nodes, station 7, removal
- No metastatic carcinoma identified (0/10).

D: Lymph nodes, station 10, removal
- No metastatic carcinoma identified (0/3).

E: Lymph nodes, station 9, removal
- No metastatic carcinoma identified (0/2).

Intraoperative Consult Diagnosis:
Frozen section is requested by Dr.

FSA1: Lung, right upper lobe, lobectomy
- Stapled margin negative for tumor

FSA2: Bronchial margin, biopsy
- No carcinoma identified.

Frozen Section Pathologist:

Clinical History:
with 3.5 cm right upper lobe lung mass.

Gross Description:
Specimen A is received for frozen section in a container labeled with the patient's name and "right upper lobe".

Specimen fixation: Received fresh for frozen section

Type of specimen/parts of lung received: Right upper lobe

Size of specimen: 20 x 14 x 6.5

Weight of specimen: 550 grams

Other attached structures: None

[page 3 of 4]
Orientation: There is a suture line which is inked black. There is a suture in the more inferior part of the lobe, identified by the surgeon as the area of interest. The staple line is removed at this point and the _____ parenchyma is re-inked black. The pleura overlying the mass is inked blue.

Tumor location: Central

Tumor size: 5 x 3 x 2.2 cm

Relationship of tumor to bronchus: It surrounds the distal bronchial structures

Distance of tumor to bronchial margin: The bronchial margin was inked black and removed. The tumor is at least 2.5 cm from the bronchial margin.

Relationship/distance of tumor to pleura: The tumor is about 0.6 cm from the blue-inked pleura.

Distance of tumor to other surgical margins: The staple line in the area of the suture was inked black and removed and approximately 4 mm of tissue was removed with the staple line. The exposed parenchyma was re-inked black and the mass was approximately 10 mm from the original margin.

Presence/absence of satellite tumor nodules: Absent

Involvement of attached structures by tumor: No

Description of nontumorous lung: The remainder of the parenchyma is diffusely congested and hemorrhagic, with no additional mass lesions grossly identified.

Digital photograph taken: No

Tissue submitted for special investigation: Representative section of tumor and normal were submitted to tissue procurement facility.

Block Summary:

FSA1 - Tumor and designated staple line

FSA2 - Bronchial margin

A1 - Vascular margin

A2 - Lymph node candidates

[page 4 of 4]
A3-A4 - Mass with respect to black inked and blue inked margins

A5 - Mass

A6 - Mass with adjacent uninvolved

A7 - Uninvolved closest tumor

A8 - Uninvolved lung distal to the mass

Specimen B is received in a formalin-filled container, labeled "station 11" and is a 0.5 x 0.4 x 0.3 cm fragment of lymphoid tissue, which is submitted entirely in block B1, NTR.

Specimen C is received in a formalin-filled container, labeled "station 7" and is a 2.4 x 0.9 x 0.7 cm fragment of lymphoid tissue, which is submitted entirely in blocks C1-C2, NTR.

Specimen D is received in a formalin-filled container, labeled "station 10" and is a 1.3 x 0.5 x 0.4 cm fragment of lymphoid tissue, which is submitted entirely in block D1, NTR.

Specimen E is received in a formalin-filled container, labeled "station 9" and is a 0.6 x 0.3 x 0.3 cm fragment of lymphoid tissue, which is submitted entirely in block E1, NTR.

P.A.:

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

The frozen section diagnoses are confirmed.

Source: NCI Genomic Data Commons file c6a1053e-4232-42f9-966e-63b5e4c4fffb (TCGA-51-4079.8BC3980D-0A81-419B-8383-400C03BE01F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).